Somatic mutation profile of tumor specimen TCGA-91-6831-01A (aliquot TCGA-91-6831-01A-11D-1855-08) from TCGA case TCGA-91-6831, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 66.9 years (24,436 days).
Specimen TCGA-91-6831-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5619e5ba-f527-4b34-915c-3244dc8c268b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-91-6831-11A (Solid Tissue Normal), aliquot TCGA-91-6831-11A-02D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acd92446-98f7-4df5-9709-0432b54209e3

The open-access MAF lists 290 somatic variants for this specimen: 229 protein-altering or splice-affecting, 57 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 197, Silent 57, Nonsense Mutation 10, Splice Site 9, Frame Shift Del 8, Frame Shift Ins 4, Intron 3, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MED28 | c.19G>T p.G7C | Missense Mutation (SNP) | VAF 14/77 reads (18%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as rs10028056, COSV99403570; called by muse, mutect2, varscan2
- ACSL1 | c.1912A>G p.M638V | Missense Mutation (SNP) | VAF 105/206 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV55662690; called by muse, mutect2, varscan2
- ACTC1 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as COSV51759066; called by muse, mutect2, varscan2
- ACTN2 | c.2677G>T p.D893Y | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142646143, COSV63971914; called by muse, mutect2, varscan2
- ACTRT2 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as rs867646845, COSV65759371; called by muse, mutect2
- ADA | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 76/126 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs765373813, COSV100596040; called by muse, mutect2, varscan2
- ADAMTS12 | c.4186G>T p.D1396Y | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61263030; called by muse, mutect2, varscan2
- ADAMTS2 | c.2854C>G p.R952G | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV52375179, COSV52383809; called by muse, mutect2, varscan2
- ADGRG2 | c.988C>G p.P330A (on ENST00000379869 / NM_001079858.3; = p.P327A on NM_005756.4) | Missense Mutation (SNP) | VAF 73/106 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV61339110; called by muse, mutect2, varscan2
- ADGRL2 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755815823, COSV54666541; called by muse, mutect2, varscan2
- AKAP14 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100538446, COSV57630191; called by muse, mutect2, varscan2
- AKT2 | c.1338G>T p.Q446H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV60908480; called by muse, mutect2, varscan2
- ALDOA | c.547G>C p.D183H (on ENST00000642816 / NM_001243177.4; = p.D129H on NM_184041.5) | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV57632467, COSV57632744; called by muse, mutect2, varscan2
- ALMS1 | c.3766A>T p.N1256Y | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV52509850; called by muse, mutect2, varscan2
- APLF | c.1369G>T p.G457W | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58144747; called by muse, mutect2, varscan2
- AQP1 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.072); catalogued as COSV61266696; called by muse, mutect2, varscan2
- ARFGEF1 | c.511G>T p.V171L | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV51608711; called by muse, mutect2, varscan2
- ASXL2 | c.2807A>G p.N936S | Missense Mutation (SNP) | VAF 120/411 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0.018); catalogued as COSV55458749; called by muse, mutect2, varscan2
- ATP13A4 | c.818A>T p.Q273L | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs745845139, COSV55069330; called by muse, mutect2, varscan2
- ATP13A4 | c.382-1G>T p.X128_splice | Splice Site (SNP) | VAF 19/61 reads (31%) | catalogued as COSV55069346; called by muse, mutect2, varscan2
- ATP1A2 | c.443A>T p.Q148L | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63403727; called by muse, mutect2, varscan2
- ATP8B1 | c.3740G>T p.R1247L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV52175762; called by muse, mutect2, varscan2
- BLMH | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 17/86 reads (20%) | catalogued as COSV55585462; called by muse, mutect2, varscan2
- BTF3 | c.293A>G p.N98S (on ENST00000380591 / NM_001037637.1; = p.N54S on NM_001207.4) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.779); catalogued as COSV100246613; called by muse, mutect2
- BTNL8 | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV51458620, COSV51458686; called by muse, mutect2, varscan2
- C1orf116 | c.1778T>C p.L593P | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63944062; called by muse, mutect2, varscan2
- C1orf141 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.199); catalogued as COSV63992635, COSV63993447; called by muse, mutect2, varscan2
- CACNA1D | c.2137G>T p.D713Y (on ENST00000350061 / NM_001128840.3; = p.D733Y on NM_000720.4) | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as COSV55443771, COSV55446989; called by muse, mutect2, varscan2
- CACNA1E | c.3327G>C p.E1109D | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as COSV100702079, COSV62394628; called by muse, mutect2, varscan2
- CAPN2 | c.2045A>G p.E682G | Missense Mutation (SNP) | VAF 73/151 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV54336153; called by muse, mutect2, varscan2
- CC2D1A | c.2731C>T p.R911W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV54308652, COSV99583051; called by muse, mutect2, varscan2
- CCNH | c.429A>G p.I143M | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99907065; called by muse, mutect2, varscan2
- CCT3 | c.4A>G p.M2V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV55289006; called by muse, mutect2
- CDC45 | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV54245396; called by muse, mutect2, varscan2
- CDH10 | c.1956C>A p.D652E | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV52580813; called by muse, mutect2, varscan2
- CDH12 | c.1069C>A p.H357N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV66405141; called by muse, mutect2, varscan2
- CDH8 | c.1493C>G p.S498C | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); catalogued as COSV54854359, COSV54867192; called by muse, mutect2, varscan2
- CDYL2 | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV73647628, COSV73647672; called by muse, mutect2, varscan2
- CFAP54 | c.5908A>C p.N1970H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV61572195; called by muse, mutect2, varscan2
- CHD5 | c.5518C>A p.Q1840K | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV52414520; called by muse, mutect2, varscan2
- CLSTN3 | c.2257A>G p.I753V | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs745614133, COSV56936254; called by muse, mutect2, varscan2
- CNBD1 | c.114T>G p.N38K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV72917014; called by muse, mutect2
- CNKSR2 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV54256125, COSV99669199; called by muse, mutect2, varscan2
- COL11A2 | c.362del p.R121Pfs*24 | Frame Shift Del (DEL) | VAF 54/141 reads (38%) | catalogued as COSV59494377; called by mutect2, pindel, varscan2
- COL6A3 | c.4427G>C p.G1476A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.044); catalogued as COSV55089316, COSV99797521; called by muse, varscan2
- CORO2B | c.702G>T p.M234I | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55953038; called by muse, mutect2, varscan2
- CPED1 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV60002234; called by muse, mutect2, varscan2
- CRISPLD1 | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV51547801; called by muse, mutect2, varscan2
- CSMD1 | c.1057G>T p.G353W | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68204455, COSV68244763; called by muse, mutect2, varscan2
- CSMD3 | c.10237C>A p.Q3413K (on ENST00000297405 / NM_001363185.1; = p.Q3244K on NM_052900.3) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52180067; called by muse, mutect2, varscan2
- CSMD3 | c.7706G>A p.C2569Y (on ENST00000297405 / NM_001363185.1; = p.C2465Y on NM_052900.3) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52180087; called by muse, mutect2
- CSMD3 | c.6325+1G>A p.X2109_splice (on ENST00000297405 / NM_001363185.1; = p.X2005_splice on NM_052900.3) | Splice Site (SNP) | VAF 28/127 reads (22%) | catalogued as COSV52180110, COSV52303536; called by muse, mutect2, varscan2
- CTNND2 | c.1645G>T p.D549Y | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100473168, COSV58888802; called by muse, mutect2, varscan2
- CUL3 | c.1616A>G p.Y539C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52364748; called by muse, mutect2, varscan2
- CXCR2 | c.754G>T p.V252F | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59280615; called by muse, mutect2, varscan2
- CYP11B1 | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV52827132; called by muse, mutect2, varscan2
- DCC | c.4048C>A p.L1350I | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT tolerated (0.87); PolyPhen benign (0.085); catalogued as COSV71431917; called by muse, mutect2, varscan2
- DCDC1 | c.745A>G p.K249E | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.558); catalogued as COSV60842446; called by muse, mutect2, varscan2
- DCHS1 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55035565; called by muse, mutect2, varscan2
- DNAH7 | c.9140T>C p.L3047S | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56764868; called by muse, mutect2, varscan2
- DOCK2 | c.4514C>A p.A1505D | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV56958607; called by muse, mutect2, varscan2
- DYTN | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 55/374 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV71752065; called by muse, mutect2, varscan2
- EIF4G1 | c.4742C>T p.S1581F (on ENST00000346169 / NM_198241.3; = p.S1386F on NM_004953.5) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV59990972; called by muse, mutect2, varscan2
- EPHA5 | c.2254G>T p.V752L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.118); catalogued as COSV56645180; called by muse, mutect2, varscan2
- ERICH3 | c.2560G>T p.G854W | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV58606652; called by muse, mutect2, varscan2
- ERICH6 | c.1718C>A p.T573N | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV55800391; called by muse, mutect2
- ETV5 | c.613A>C p.K205Q | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV60502095; called by muse, mutect2, varscan2
- EXOC6B | c.2171A>T p.Q724L | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs111624023, COSV55555125; called by muse, mutect2, varscan2
- F2R | c.1034C>A p.T345N | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.084); catalogued as COSV100058240; called by muse, mutect2, varscan2
- FAT4 | c.3505C>T p.R1169W | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as rs190175933; called by muse, mutect2, varscan2
- FBN2 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as rs1453427225, COSV52512938; called by muse, mutect2, varscan2
- FCSK | c.318G>T p.R106S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55370763; called by muse, mutect2, varscan2
- FRMD3 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58461401; called by muse, mutect2, varscan2
- FSHR | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV58623602; called by muse, mutect2, varscan2
- GATA5 | c.914-2A>T p.X305_splice | Splice Site (SNP) | VAF 41/88 reads (47%) | catalogued as COSV53345958; called by muse, mutect2, varscan2
- GBP3 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs773385974, COSV52518508; called by muse, mutect2, varscan2
- GEM | c.768G>T p.Q256H | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV52597361; called by muse, mutect2
- GLT1D1 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 24/280 reads (9%) | catalogued as COSV55881735, COSV55882010; called by muse, mutect2
- GPBP1L1 | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV51969342; called by muse, mutect2, varscan2
- GRAMD1C | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.999); catalogued as COSV63982735; called by muse, mutect2, varscan2
- GRM5 | c.802T>A p.L268M | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59605070; called by muse, mutect2, varscan2
- HDAC2 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.395); catalogued as rs1301976032, COSV64038180; called by muse, mutect2, varscan2
- HEMGN | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV52326366; called by muse, mutect2, varscan2
- HMCN1 | c.6752del p.G2251Afs*42 | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | catalogued as COSV99637440; called by mutect2, pindel, varscan2
- HPS4 | c.1622T>A p.M541K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV61103448; called by muse, mutect2, varscan2
- ICAM5 | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs537423937, COSV55747303; called by muse, mutect2, varscan2
- ICE2 | c.2140G>T p.D714Y | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (1); PolyPhen possibly damaging (0.458); catalogued as COSV55031436; called by muse, mutect2, varscan2
- IFNA4 | c.230T>A p.I77N | Missense Mutation (SNP) | VAF 11/296 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV101426985; called by muse, mutect2
- IGSF10 | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138815446; called by muse, mutect2, varscan2
- IREB2 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.067); catalogued as rs751197364, COSV51922631; called by muse, mutect2
- IRX1 | c.1412C>G p.P471R | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV57359468; called by muse, mutect2, varscan2
- KALRN | c.7970C>T p.S2657L (on ENST00000360013 / NM_001024660.4; = p.S960L on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as rs754909011, COSV52256277; called by muse, mutect2, varscan2
- KDM1A | c.2399G>A p.G800E | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56501117; called by muse, mutect2, varscan2
- KDM3B | c.2218A>T p.T740S | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV58690727; called by muse, mutect2, varscan2
- KIDINS220 | c.3827T>C p.M1276T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV56753396; called by muse, mutect2, varscan2
- KIF4B | c.664C>A p.Q222K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.314); catalogued as COSV70529265; called by muse, mutect2, varscan2
- KIF4B | c.2993A>T p.Q998L | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV70529271; called by muse, mutect2, varscan2
- KLHL38 | c.1512T>A p.C504* | Nonsense Mutation (SNP) | VAF 6/92 reads (7%) | catalogued as COSV58087364; called by muse, mutect2
- KRT72 | c.723G>T p.M241I | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as COSV53374338; called by muse, mutect2, varscan2
- KRT74 | c.1276C>T p.Q426* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as COSV59771438; called by muse, mutect2, varscan2
- KRTAP10-4 | c.1136C>A p.S379Y | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV59962093, COSV59966635; called by muse, mutect2, varscan2
- LAMB1 | c.3295T>C p.F1099L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as COSV55964558; called by muse, mutect2, varscan2
- LCT | c.3972G>T p.W1324C | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51549319; called by muse, mutect2, varscan2
- LILRA1 | c.1260A>G p.S420= | Splice Region (SNP) | VAF 56/128 reads (44%) | catalogued as COSV52180729; called by muse, mutect2, varscan2
- LILRB1 | c.674C>T p.P225L (on ENST00000427581; = p.P189L on NM_006669.6) | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as rs367841149; called by muse, mutect2, varscan2
- LMBR1L | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV57267652; called by muse, mutect2, varscan2
- LNX1 | c.1988A>G p.N663S (on ENST00000263925 / NM_001126328.3; = p.N567S on NM_032622.2) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as rs369294756; called by muse, mutect2, varscan2
- LONRF3 | c.851C>G p.S284C | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59152213; called by muse, mutect2, varscan2
- LRRTM3 | c.1536+2T>C p.X512_splice | Splice Site (SNP) | VAF 17/50 reads (34%) | catalogued as COSV63665418; called by muse, mutect2, varscan2
- MAGEB4 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.28); PolyPhen benign (0.366); catalogued as rs267606430, COSV100854565, COSV100854815; called by muse, mutect2, varscan2
- MAST1 | c.2804G>C p.S935T | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV52246810; called by muse, mutect2, varscan2
- MDC1 | c.2222-1G>T p.X741_splice | Splice Site (SNP) | VAF 27/46 reads (59%) | catalogued as COSV64524598; called by muse, mutect2, varscan2
- MERTK | c.2027A>G p.Y676C | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54928982; called by muse, mutect2, varscan2
- MGAT5 | c.259G>C p.A87P | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV56093315, COSV56096473; called by muse, mutect2
- MIA2 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as COSV54483443; called by muse, mutect2, varscan2
- MMD2 | c.585C>G p.F195L (on ENST00000404774 / NM_001100600.2; = p.F171L on NM_198403.4) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV101286889, COSV68660294; called by muse, mutect2, varscan2
- MMP13 | c.461C>A p.T154N | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV52824019; called by muse, mutect2, varscan2
- MPPED1 | c.420C>G p.Y140* | Nonsense Mutation (SNP) | VAF 59/91 reads (65%) | catalogued as COSV68837310, COSV68838096; called by muse, mutect2, varscan2
- MUC16 | c.3891G>T p.M1297I | Missense Mutation (SNP) | VAF 103/178 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV67465624; called by muse, mutect2, varscan2
- MUC17 | c.5978G>C p.S1993T | Missense Mutation (SNP) | VAF 157/447 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV60288430; called by muse, mutect2, varscan2
- MUC17 | c.10328C>T p.A3443V | Missense Mutation (SNP) | VAF 102/540 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1187838914, COSV60288438; called by muse, mutect2, varscan2
- MYO1D | c.1879G>T p.A627S | Missense Mutation (SNP) | VAF 84/179 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1449388673, COSV59013068; called by muse, mutect2, varscan2
- NCKAP5 | c.2290G>T p.V764L | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as COSV58443797, COSV58466451; called by muse, mutect2, varscan2
- NEB | c.5158C>A p.P1720T | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51396701; called by muse, mutect2, varscan2
- NETO1 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV100197982; called by muse, mutect2, varscan2
- NOS1 | c.1539G>C p.Q513H | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV57612264; called by muse, mutect2, varscan2
- NPHS1 | c.1633C>G p.P545A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.197); catalogued as COSV62287813; called by muse, mutect2, varscan2
- NRXN3 | c.551C>A p.S184* | Nonsense Mutation (SNP) | VAF 32/77 reads (42%) | catalogued as COSV73584484; called by muse, mutect2, varscan2
- OBSCN | c.13389G>T p.E4463D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV52773821; called by muse, mutect2, varscan2
- ODC1 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs116522452, COSV52172292; called by muse, mutect2, varscan2
- OR10K1 | c.844A>T p.T282S | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56871928; called by muse, mutect2, varscan2
- OR4K1 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.612); catalogued as rs776240917, COSV53460164; called by muse, mutect2, varscan2
- OR4S1 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.648); catalogued as rs762937100, COSV100180128, COSV60679827; called by muse, mutect2, varscan2
- OR51I2 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV58298708, COSV58299400; called by muse, mutect2, varscan2
- OR5P2 | c.342G>T p.M114I | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100271142; called by muse, mutect2, varscan2
- OR5T2 | c.813A>C p.E271D | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV57589132; called by muse, mutect2, varscan2
- OR6N2 | c.609T>A p.N203K | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59411437; called by muse, mutect2, varscan2
- OR7C1 | c.664G>C p.V222L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as COSV99934730; called by muse, mutect2, varscan2
- OR8B2 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100899262, COSV66665073; called by muse, mutect2, varscan2
- OR8G5 | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV100422156; called by muse, mutect2, varscan2
- OSR1 | c.554C>G p.T185S | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV55345533; called by muse, mutect2, varscan2
- PAFAH1B2 | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59166756; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1091C>G p.S364* (on ENST00000259318 / NM_001136562.3; = p.S595* on NM_007203.5) | Nonsense Mutation (SNP) | VAF 30/52 reads (58%) | catalogued as COSV52176190; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1540C>T p.Q514* (on ENST00000259318 / NM_001136562.3; = p.Q745* on NM_007203.5) | Nonsense Mutation (SNP) | VAF 48/86 reads (56%) | catalogued as rs1347733309, COSV52176222; called by muse, mutect2, varscan2
- PCDHA1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); catalogued as rs148838866, COSV100974288; called by muse, mutect2, varscan2
- PCDHB4 | c.1697A>G p.N566S | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV52022386; called by muse, mutect2, varscan2
- PCDHB5 | c.967G>T p.G323C | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50651667; called by muse, mutect2, varscan2
- PCDHB8 | c.1399C>G p.P467A | Missense Mutation (SNP) | VAF 36/808 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV50767838; called by muse, mutect2
- PDK2 | c.1046T>C p.M349T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1248422088, COSV50303654; called by muse, mutect2, varscan2
- PEX2 | c.846G>T p.K282N | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV100824664; called by muse, mutect2, varscan2
- PHLPP2 | c.1471A>T p.R491W | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV62424494; called by muse, mutect2, varscan2
- PKHD1L1 | c.6013A>T p.N2005Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV65742887; called by muse, mutect2, varscan2
- PKP1 | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV55821150; called by muse, mutect2, varscan2
- PLA2G7 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422009776, COSV51260421; called by muse, mutect2, varscan2
- PRUNE2 | c.1808del p.N603Ifs*11 | Frame Shift Del (DEL) | VAF 13/79 reads (16%) | catalogued as rs754369178; called by mutect2, pindel, varscan2
- PSKH2 | c.955T>G p.W319G | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52610471; called by muse, mutect2, varscan2
- PXDN | c.3967G>A p.G1323R | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV53233865; called by muse, mutect2, varscan2
- RAB2A | c.47-1G>C p.X16_splice | Splice Site (SNP) | VAF 9/117 reads (8%) | catalogued as COSV52911649; called by muse, mutect2
- RAD51AP2 | c.755G>C p.R252T | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV67588054; called by muse, mutect2, varscan2
- RARS2 | c.1069G>C p.V357L | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65761071; called by muse, mutect2
- RELN | c.4300A>G p.T1434A | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.863); catalogued as COSV59002092; called by muse, mutect2, varscan2
- RESF1 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as rs755106637, COSV57022067; called by muse, mutect2, varscan2
- RGL2 | c.420-1G>T p.X140_splice | Splice Site (SNP) | VAF 49/105 reads (47%) | catalogued as COSV69916168; called by muse, mutect2, varscan2
- ROS1 | c.6563A>G p.D2188G | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV63855147; called by muse, mutect2, varscan2
- RTN4IP1 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV64805410; called by muse, mutect2, varscan2
- SDC3 | c.162C>G p.N54K | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV59579430; called by muse, mutect2, varscan2
- SEMA4A | c.175A>G p.K59E | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV61772676; called by muse, mutect2, varscan2
- SEPTIN10 | c.458A>G p.Y153C | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs752044871, COSV61780247, COSV61781670; called by muse, mutect2, varscan2
- SI | c.1925C>G p.T642R | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52278452; called by muse, mutect2, varscan2
- SIGLEC12 | c.1556C>A p.T519K (on ENST00000291707 / NM_053003.4; = p.T401K on NM_033329.2) | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV52461491; called by muse, mutect2, varscan2
- SKIL | c.1607G>T p.R536I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV52059835; called by muse, mutect2, varscan2
- SLC39A3 | c.766G>T p.V256L | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV99514037; called by muse, mutect2, varscan2
- SLC6A18 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57251274; called by muse, mutect2, varscan2
- SLCO1B1 | c.1126A>T p.I376F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57011163; called by muse, mutect2, varscan2
- SOX7 | c.1113C>G p.I371M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58730793; called by muse, mutect2, varscan2
- SPEM1 | c.856C>A p.P286T | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV57210199; called by muse, mutect2, varscan2
- SPIN3 | c.712G>C p.V238L | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as COSV66529193; called by muse, mutect2, varscan2
- SRCAP | c.7399C>T p.P2467S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.61); catalogued as rs1469573832, COSV52672599; called by muse, mutect2
- ST6GAL2 | c.1304C>G p.S435C | Missense Mutation (SNP) | VAF 101/259 reads (39%) | PolyPhen probably damaging (1); catalogued as COSV62416630; called by muse, mutect2, varscan2
- SYDE2 | c.2731G>C p.E911Q | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.088); catalogued as COSV58323000; called by muse, mutect2, varscan2
- SYT10 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 45/131 reads (34%) | catalogued as rs1204055233, COSV57340483; called by muse, mutect2, varscan2
- TAS2R20 | c.308G>T p.S103I | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67855831; called by muse, mutect2, varscan2
- TEKT4 | c.578G>C p.R193P | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs782484523, COSV54624782; called by muse, mutect2
- TET1 | c.6007G>T p.D2003Y | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65384761; called by muse, mutect2, varscan2
- TG | c.4967G>A p.S1656N | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.107); catalogued as rs1453114223, COSV55076094; called by muse, mutect2, varscan2
- TKT | c.1546T>A p.L516M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56245314; called by muse, mutect2, varscan2
- TLR6 | c.1784T>G p.M595R | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV67935234; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3695A>T p.N1232I | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs1453438976, COSV64101001; called by muse, mutect2, varscan2
- TNRC6C | c.3908C>G p.P1303R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV56945193; called by muse, mutect2, varscan2
- TP53 | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52689817, COSV52759537, COSV52925149; called by muse, mutect2, varscan2
- TPR | c.3070A>G p.R1024G | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV66601384; called by muse, mutect2, varscan2
- TRAK2 | c.870G>T p.Q290H | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60272024; called by muse, mutect2, varscan2
- TRIM48 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70161554; called by muse, mutect2, varscan2
- TTC17 | c.3127C>T p.H1043Y | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV50008532; called by muse, mutect2, varscan2
- TTN | c.63137T>A p.V21046E (on ENST00000591111; = p.V13622E on NM_003319.4) | Missense Mutation (SNP) | VAF 29/83 reads (35%) | PolyPhen benign (0.003); catalogued as COSV60059483; called by muse, mutect2, varscan2
- TTN | c.18128G>T p.G6043V (on ENST00000591111; = p.G5116V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | PolyPhen probably damaging (1); catalogued as COSV100588655; called by muse, mutect2, varscan2
- TTN | c.13039G>C p.D4347H (on ENST00000591111; = p.D4301H on NM_003319.4) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as CM1413715, COSV60000338, COSV60059546; called by muse, mutect2, varscan2
- UBE2J1 | c.520C>A p.Q174K | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70561407; called by muse, mutect2, varscan2
- USP9X | c.7251G>T p.W2417C | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV61069110; called by muse, mutect2, varscan2
- VPS28 | c.38-1G>T p.X13_splice | Splice Site (SNP) | VAF 15/25 reads (60%) | catalogued as COSV52871908; called by muse, mutect2, varscan2
- WDR13 | c.938A>G p.D313G | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99488990; called by muse, mutect2, varscan2
- WDR64 | c.2627T>A p.V876E | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV63795974, COSV63801529; called by muse, mutect2, varscan2
- ZCCHC2 | c.2014A>G p.T672A | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV54037728; called by muse, mutect2, varscan2
- ZDHHC19 | c.187G>T p.V63F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV56348721; called by muse, mutect2, varscan2
- ZFP91 | c.953G>T p.C318F | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60158896; called by muse, mutect2, varscan2
- ZNF253 | c.104A>C p.E35A | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63037159; called by muse, mutect2, varscan2
- ZNF28 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 89/361 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100354201; called by muse, mutect2, varscan2
- ZNF304 | c.1051G>T p.V351F | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.627); catalogued as COSV56584324; called by muse, mutect2, varscan2
- ZNF350 | c.1568A>G p.Y523C | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV54708768; called by muse, mutect2, varscan2
- ZNF395 | c.1441G>T p.G481W | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60428585, COSV60430567; called by muse, mutect2, varscan2
- ZNF431 | c.1148G>T p.W383L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as COSV100218401; called by muse, mutect2, varscan2
- ZNF431 | c.1149G>T p.W383C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.092); catalogued as COSV100218403; called by muse, mutect2, varscan2
- ZNF608 | c.3910C>G p.Q1304E | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.954); catalogued as COSV60437743; called by muse, mutect2, varscan2
- ZNF613 | c.984G>T p.R328S (on ENST00000293471 / NM_001031721.4; = p.R292S on NM_024840.4) | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV53271795; called by muse, mutect2, varscan2
- ZNF678 | c.476G>T p.G159V (on ENST00000343776 / NM_001367910.1; = p.G214V on NM_178549.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59382298, COSV59382984; called by muse, mutect2, varscan2
- ZRANB3 | c.1870G>C p.G624R | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as COSV99922270; called by muse, mutect2, varscan2
- ALKBH6 | c.-101+1del | Splice Site (DEL) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- ASB3 | c.95dup p.R34Pfs*7 | Frame Shift Ins (INS) | VAF 65/199 reads (33%) | called by mutect2, pindel, varscan2
- CHRM2 | c.157dup p.H53Pfs*17 | Frame Shift Ins (INS) | VAF 53/155 reads (34%) | called by mutect2, pindel, varscan2
- COL1A2 | c.51del p.L17Ffs*3 | Frame Shift Del (DEL) | VAF 32/217 reads (15%) | called by mutect2, pindel, varscan2
- EML5 | c.1346del p.G449Dfs*38 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by mutect2, pindel, varscan2
- IGKV1-12 | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 78/562 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PPIAL4A | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 110/178 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- PRAG1 | c.542_544delinsA p.S181Nfs*56 | Frame Shift Del (DEL) | VAF 61/136 reads (45%) | called by pindel, varscan2*
- RPGRIP1L | c.959dup p.R321Afs*8 | Frame Shift Ins (INS) | VAF 22/63 reads (35%) | called by mutect2, pindel, varscan2
- SIMC1 | c.1262_1263delinsT p.P421Lfs*14 (on ENST00000443967 / NM_001308196.1; = p.P440Lfs*14 on NM_001308195.2) | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by pindel, varscan2*
- SOGA1 | c.889_895del p.R297Wfs*62 | Frame Shift Del (DEL) | VAF 14/140 reads (10%) | called by mutect2, pindel, varscan2
- TIE1 | c.1535dup p.T513Dfs*32 | Frame Shift Ins (INS) | VAF 33/110 reads (30%) | called by mutect2, pindel, varscan2
- TRAC | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AC100868.1 | c.1149C>A p.T383= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs760476128, COSV99224955; called by muse, mutect2, varscan2
- AGRN | c.1650C>G p.T550= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs201719609, COSV65069583; called by muse, mutect2, varscan2
- ALK | c.1317C>T p.S439= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs748996936, COSV66568239, COSV66588003; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGEF25 | c.231C>G p.G77= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV54086556; called by muse, mutect2, varscan2
- CDH8 | c.1662C>A p.S554= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV54867183; called by muse, mutect2, varscan2
- CHST1 | c.1086C>T p.F362= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as rs777806565, COSV100346389, COSV57323599; called by muse, mutect2, varscan2
- CLCNKA | c.1797G>T p.L599= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV58891605; called by muse, mutect2, varscan2
- CLPX | c.1509G>A p.V503= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as COSV55644512; called by muse, mutect2, varscan2
- CYP19A1 | c.60C>T p.A20= | Silent (SNP) | VAF 60/147 reads (41%) | catalogued as COSV53057588; called by muse, mutect2, varscan2
- DNAJB11 | c.483G>A p.R161= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV54002610; called by muse, mutect2, varscan2
- DOC2A | c.111C>A p.P37= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV58751401; called by muse, mutect2, varscan2
- DUSP26 | c.558A>G p.R186= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV99823277; called by muse, mutect2, varscan2
- EGFLAM | c.2496A>T p.I832= (on ENST00000354891 / NM_001205301.2; = p.I824= on NM_152403.4) | Silent (SNP) | VAF 57/278 reads (21%) | catalogued as COSV59302101; called by muse, mutect2, varscan2
- F13A1 | c.369C>G p.V123= | Silent (SNP) | VAF 10/141 reads (7%) | catalogued as COSV53558448; called by muse, mutect2
- FBN3 | c.7737C>T p.C2579= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs767651414, COSV54460531; called by muse, mutect2, varscan2
- FOLH1 | c.2040G>T p.G680= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV57049106; called by muse, mutect2, varscan2
- FOXN1 | c.1791G>A p.L597= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV56881787; called by muse, mutect2
- FSHR | c.651C>A p.A217= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV58623595; called by muse, mutect2, varscan2
- FYN | c.684A>T p.V228= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV57614275; called by muse, mutect2, varscan2
- HPCAL4 | c.555G>A p.L185= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as COSV65716270; called by muse, mutect2, varscan2
- IMP4 | c.123G>T p.L41= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as COSV52091727, COSV99383561; called by muse, mutect2, varscan2
- KCNA1 | c.372G>A p.E124= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV66837336; called by muse, mutect2, varscan2
- KCNH7 | c.1173G>A p.Q391= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV59796608; called by muse, mutect2, varscan2
- KIF19 | c.2920C>A p.R974= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV63429424, COSV63431081; called by muse, mutect2, varscan2
- LAMB4 | c.3216C>A p.V1072= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV52718982, COSV52720881; called by muse, mutect2, varscan2
- LELP1 | c.255C>G p.S85= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV64202453; called by muse, mutect2, varscan2
- LEMD1 | c.42C>T p.N14= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV65671500; called by muse, mutect2, varscan2
- LRRC8D | c.2370C>G p.L790= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV61579191; called by muse, mutect2, varscan2
- MAD2L1BP | c.405C>T p.L135= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs1315995398, COSV64664841; called by muse, mutect2, varscan2
- MFSD1 | c.514C>T p.L172= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV51840663; called by muse, varscan2
- NPAP1 | c.2517C>T p.T839= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV61506998; called by muse, mutect2, varscan2
- OR5AU1 | c.801C>T p.S267= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV100436033; called by muse, mutect2, varscan2
- OR8J1 | c.852T>A p.P284= | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as COSV57317125, COSV57318229; called by muse, mutect2, varscan2
- OXSR1 | c.1134G>T p.V378= | Silent (SNP) | VAF 52/109 reads (48%) | catalogued as COSV61258699; called by muse, mutect2, varscan2
- PALD1 | c.1938G>T p.R646= | Silent (SNP) | VAF 48/146 reads (33%) | catalogued as COSV54973423; called by muse, mutect2, varscan2
- PARP4 | c.3390A>T p.R1130= | Silent (SNP) | VAF 90/153 reads (59%) | catalogued as COSV67961762; called by muse, mutect2, varscan2
- PLEKHA6 | c.2853G>A p.V951= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV55333700; called by muse, mutect2, varscan2
- PTGER2 | c.165G>T p.G55= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99817245; called by mutect2, varscan2
- RFX2 | c.1905C>T p.F635= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs147306532; called by muse, mutect2, varscan2
- RNF152 | c.304C>T p.L102= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV57185856; called by muse, mutect2, varscan2
- SCIN | c.1689G>A p.E563= (on ENST00000297029 / NM_001112706.3; = p.E316= on NM_033128.3) | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV51692686; called by muse, mutect2, varscan2
- SGCA | c.96G>A p.V32= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV56249325; called by muse, mutect2, varscan2
- SLC20A1 | c.1959C>T p.A653= | Silent (SNP) | VAF 45/145 reads (31%) | catalogued as COSV55611332; called by muse, mutect2, varscan2
- SMC1A | c.3264G>T p.L1088= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV59129227; called by muse, mutect2
- SNTG1 | c.717C>A p.V239= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV52443397; called by muse, mutect2, varscan2
- STAB2 | c.6798C>G p.G2266= | Silent (SNP) | VAF 46/179 reads (26%) | catalogued as COSV66338931; called by muse, mutect2, varscan2
- STAT6 | c.69C>T p.P23= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs772021515, COSV55671013; called by muse, mutect2
- STK32B | c.807C>T p.S269= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV51487153; called by muse, mutect2, varscan2
- SYT3 | c.250C>A p.R84= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as rs185774466, COSV58895719, COSV58896749; called by muse, mutect2, varscan2
- TOLLIP | c.180A>G p.V60= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV99719368; called by muse, mutect2, varscan2
- TTN | c.29226C>A p.T9742= (on ENST00000591111; = p.T8815= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/213 reads (15%) | catalogued as COSV60059519; called by muse, mutect2, varscan2
- TTN | c.18129G>T p.G6043= (on ENST00000591111; = p.G5116= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV59961374; called by muse, mutect2, varscan2
- TUT4 | c.48G>A p.K16= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV57114063; called by muse, mutect2, varscan2
- ZC3H13 | c.3510G>T p.T1170= | Silent (SNP) | VAF 77/162 reads (48%) | catalogued as rs778100703, COSV54453681, COSV54463809; called by muse, mutect2, varscan2
- ZNF318 | c.1884C>T p.S628= | Silent (SNP) | VAF 111/209 reads (53%) | catalogued as COSV58932576; called by muse, mutect2, varscan2
- ZNF391 | c.426T>C p.C142= | Silent (SNP) | VAF 22/144 reads (15%) | catalogued as COSV99772318; called by muse, mutect2, varscan2
- ZP2 | c.1047A>G p.T349= | Silent (SNP) | VAF 4/82 reads (5%) | catalogued as rs1238457241, COSV54813874; called by muse, mutect2
- DST | c.4296+4104T>C | Intron (SNP) | VAF 19/110 reads (17%) | catalogued as COSV99749347; called by muse, mutect2, varscan2
- MACF1 | c.15832-11122G>T | Intron (SNP) | VAF 36/93 reads (39%) | catalogued as COSV57120947; called by muse, mutect2, varscan2
- POM121C | chr7:75416095 C>T | 3'Flank (SNP) | VAF 4/25 reads (16%) | called by mutect2, varscan2
- ZNF783 | c.802+3021G>T | Intron (SNP) | VAF 31/84 reads (37%) | catalogued as COSV100954053, COSV65184983; called by muse, mutect2, varscan2
